Somatic mutation profile of tumor specimen 3f957017-d081-45f4-b458-ec3f8d (aliquot 3f957017-d081-45f4-b458-ec3f8d_D6) from CPTAC case 05BR016, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 78.1 years (28,530 days).
Specimen 3f957017-d081-45f4-b458-ec3f8d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fd2d202-ad00-4376-acca-a4181c7eea8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7a087328-9980-4488-ac9b-ba9550 (Blood Derived Normal), aliquot 7a087328-9980-4488-ac9b-ba9550_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd626470-01b0-41f1-8ea7-7e9154b7a415

The open-access MAF lists 51 somatic variants for this specimen: 31 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 14, 3'Flank 3, Frame Shift Ins 2, 5'UTR 1, RNA 1, 5'Flank 1, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs545576634; called by muse, mutect2, varscan2
- BEAN1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as rs747973755; called by muse, mutect2, varscan2
- CCDC43 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778956757; called by muse, mutect2, varscan2
- CCL4 | c.196C>G p.Q66E | Missense Mutation (SNP) | VAF 152/520 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.492); catalogued as rs1047078448; called by muse, mutect2, varscan2
- CDHR2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs759138873; called by muse, mutect2, varscan2
- DLGAP4 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs749843319, COSV59422498, COSV59425086; called by muse, mutect2, varscan2
- NLRC3 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs751267758; called by muse, mutect2, varscan2
- PDGFD | c.640dup p.I214Nfs*5 | Frame Shift Ins (INS) | VAF 135/416 reads (32%) | catalogued as rs1333395128; called by mutect2, varscan2
- RUNX1T1 | c.1778C>T p.P593L (on ENST00000265814 / NM_001198628.1; = p.P566L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/303 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV56143335, COSV56149645; called by muse, mutect2, varscan2
- WNT7B | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as rs1253848550; called by muse, mutect2
- ZFP30 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 142/274 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100665872; called by muse, mutect2, varscan2
- ADGRA2 | c.4002C>A p.S1334R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- ARHGEF12 | c.1894dup p.T632Nfs*8 | Frame Shift Ins (INS) | VAF 56/189 reads (30%) | called by mutect2, pindel, varscan2
- C5AR1 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 238/457 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CLUH | c.76C>T p.L26F (on ENST00000435359; = p.L64F on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DPP8 | c.136C>T p.P46S (on ENST00000341861 / NM_001320875.2; = p.P30S on NM_017743.6) | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- FOXA1 | c.851_866del p.G284Afs*32 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- GK | c.244A>T p.I82F | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- GNAS | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- KDM5C | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2
- MBD5 | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PROX2 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RASAL3 | c.2791G>T p.G931C | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RLIM | c.170-14_170del p.X57_splice | Splice Site (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- SHD | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2
- SHLD3 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 155/296 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SYK | c.1651A>G p.S551G | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TOMM70 | c.640T>A p.C214S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TTC6 | c.364A>G p.K122E (on ENST00000267368; = p.K1488E on NM_001310135.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- XIAP | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF98 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 94/444 reads (21%) | called by muse, varscan2
- DCAF12L1 | c.1167C>T p.A389= | Silent (SNP) | VAF 22/336 reads (7%) | called by muse, mutect2
- EMILIN3 | c.2217G>A p.T739= | Silent (SNP) | VAF 108/282 reads (38%) | catalogued as rs769617233; called by muse, mutect2, varscan2
- HEY2 | c.690G>A p.T230= | Silent (SNP) | VAF 74/213 reads (35%) | catalogued as COSV64240015; called by muse, mutect2, varscan2
- HLF | c.336G>A p.G112= | Silent (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- HOMER3 | c.984G>A p.A328= | Silent (SNP) | VAF 88/147 reads (60%) | catalogued as rs369977374; called by muse, mutect2, varscan2
- INSYN2A | c.1413C>T p.H471= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs575404993, COSV54750366; called by muse, mutect2, varscan2
- JPH4 | c.204C>T p.G68= | Silent (SNP) | VAF 79/248 reads (32%) | called by muse, mutect2, varscan2
- KIF9 | c.696A>G p.S232= | Silent (SNP) | VAF 15/263 reads (6%) | called by muse, mutect2
- MUC5B | c.15525C>T p.G5175= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs972531232; called by muse, mutect2, varscan2
- PTX3 | c.252G>A p.E84= | Silent (SNP) | VAF 83/224 reads (37%) | called by muse, mutect2, varscan2
- SNPH | c.1083C>A p.P361= | Silent (SNP) | VAF 27/231 reads (12%) | called by muse, mutect2, varscan2
- SPTBN5 | c.3339A>G p.Q1113= | Silent (SNP) | VAF 247/401 reads (62%) | catalogued as rs748376432; called by muse, mutect2, varscan2
- TRPM4 | c.3369G>A p.T1123= | Silent (SNP) | VAF 137/500 reads (27%) | catalogued as rs747058283, COSV53262881; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF394 | c.1479G>A p.G493= | Silent (SNP) | VAF 81/231 reads (35%) | catalogued as rs754566877; called by muse, mutect2, varscan2
- AC090151.1 | chr8:54699561 C>G | 3'Flank (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505167 ins T | 5'Flank (INS) | VAF 47/115 reads (41%) | catalogued as rs752288826; called by mutect2, varscan2
- CNOT4 | chr7:135384714 T>C | 3'Flank (SNP) | VAF 62/191 reads (32%) | called by muse, mutect2, varscan2
- CTSLP8 | n.965G>T | RNA (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- FKBPL | c.-49C>G | 5'UTR (SNP) | VAF 41/125 reads (33%) | catalogued as rs1279610603; called by muse, mutect2, varscan2
- HOXA7 | chr7:27153001 G>A | 3'Flank (SNP) | VAF 58/162 reads (36%) | called by muse, mutect2, varscan2
